Somatic mutation profile of tumor specimen MP2PRT-PATIYF-TMP1-A (aliquot MP2PRT-PATIYF-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATIYF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,792 days).
Specimen MP2PRT-PATIYF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5b55795-f7f5-45a0-9edd-4391b35623ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATIYF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATIYF-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42a3f04a-54a8-4e5c-9aea-48d5dbcd750c

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM9B | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.954); catalogued as rs201899161, COSV59119986; called by muse, mutect2, varscan2
- IFT122 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV56207031; called by muse, mutect2, varscan2
- KRT14 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51420980; called by muse, mutect2, varscan2
- NCR1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 204/566 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs139654571; called by muse, mutect2, varscan2
- ODF4 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 141/307 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs202042653, COSV100071958; called by muse, mutect2, varscan2
- TRABD2A | c.1406G>A p.R469H (on ENST00000409520 / NM_001277053.2; = p.R420H on NM_001080824.3) | Missense Mutation (SNP) | VAF 121/341 reads (35%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs199868738; called by muse, varscan2
- ZNF37A | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 132/330 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs768161470, COSV61072715; called by muse, mutect2, varscan2
- ARHGEF26 | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2
- FSIP2 | c.18869T>A p.V6290E | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NEDD4 | c.738G>C p.E246D | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2
- RYR2 | c.10123A>T p.R3375* | Nonsense Mutation (SNP) | VAF 100/255 reads (39%) | called by muse, mutect2, varscan2
- SLC35F1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SPATA31A7 | c.1801C>A p.Q601K | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- SYNPO2L | c.405G>C p.E135D | Missense Mutation (SNP) | VAF 200/458 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ABCA9 | c.4188C>T p.D1396= | Silent (SNP) | VAF 95/304 reads (31%) | catalogued as rs552343216, COSV60619980; called by muse, mutect2, varscan2
- BAG6 | c.1320T>C p.I440= | Silent (SNP) | VAF 191/545 reads (35%) | called by muse, mutect2, varscan2
- CEP170B | c.1719C>T p.I573= (on ENST00000453495; = p.I502= on NM_015005.3) | Silent (SNP) | VAF 127/362 reads (35%) | catalogued as rs775562903; called by muse, mutect2, varscan2
- GALNT5 | c.246G>T p.G82= | Silent (SNP) | VAF 108/312 reads (35%) | called by muse, mutect2, varscan2
- IGHV3-23 | chr14:106268601 CTGTGT>TGAC | Silent (DEL) | VAF 61/199 reads (31%) | called by pindel, varscan2*
- PAPPA2 | c.249C>T p.P83= | Silent (SNP) | VAF 186/450 reads (41%) | catalogued as rs1419744359, COSV62776409, COSV62779286; called by muse, mutect2, varscan2
- CRYBG2 | chr1:26354575 G>A | 5'Flank (SNP) | VAF 30/606 reads (5%) | called by muse, mutect2
